Somatic mutation profile of tumor specimen HCM-BROD-0235-C16-06A (aliquot HCM-BROD-0235-C16-06A-01D-A79C-36) from HCMI case HCM-BROD-0235-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.7 years (18,528 days).
Specimen HCM-BROD-0235-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4389905-1668-4560-89a5-549d4f797bdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0235-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0235-C16-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34de16cb-8e52-43ee-9c67-2629e1e18eb4

The open-access MAF lists 52 somatic variants for this specimen: 36 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 32, Silent 16, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCM2L | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 350/475 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs138375629; called by muse, mutect2, varscan2
- CD163 | c.1547G>T p.C516F | Missense Mutation (SNP) | VAF 106/463 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63136477; called by muse, mutect2, varscan2
- CDH1 | c.641T>C p.L214P | Missense Mutation (SNP) | VAF 277/307 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as CM065995, COSV55734778, COSV55738543, COSV55741457; called by muse, mutect2, varscan2
- DDX18 | c.914T>C p.I305T | Missense Mutation (SNP) | VAF 237/346 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs770462842; called by muse, mutect2, varscan2
- DDX28 | c.757C>A p.Q253K | Missense Mutation (SNP) | VAF 512/572 reads (90%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs140829287; called by muse, mutect2, varscan2
- DHRSX | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 116/640 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1426778105; called by muse, mutect2, varscan2
- HYDIN | c.8236G>A p.V2746M | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV59270825; called by muse, mutect2, varscan2
- MKRN3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 370/742 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs781005844, COSV58808823; called by muse, mutect2, varscan2
- MMP9 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 178/963 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs371340871, COSV63433763; called by muse, mutect2, varscan2
- MUC12 | c.1523C>T p.P508L (on ENST00000379442; = p.P365L on NM_001164462.1) | Missense Mutation (SNP) | VAF 109/3057 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs774154750, COSV101060102; called by muse, mutect2
- OR4A15 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 182/321 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); catalogued as rs201833967; called by muse, mutect2, varscan2
- PXDN | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 233/349 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as rs755575492, COSV53233112; called by muse, mutect2, varscan2
- QRFPR | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 66/149 reads (44%) | catalogued as rs767056594, COSV57676046; called by muse, mutect2, varscan2
- SPECC1L | c.2773C>T p.R925W | Missense Mutation (SNP) | VAF 88/405 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs199614545; called by muse, mutect2, varscan2
- TNNT3 | c.581G>A p.R194H (on ENST00000397301 / NM_001367846.1; = p.R183H on NM_006757.4) | Missense Mutation (SNP) | VAF 81/280 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs755730812; called by muse, mutect2, varscan2
- USP17L2 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 129/1024 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs767583659, COSV61556104; called by muse, mutect2, varscan2
- ZNF334 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 85/470 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs759953169, COSV61618453; called by muse, mutect2, varscan2
- AKAP12 | c.2722G>C p.E908Q | Missense Mutation (SNP) | VAF 98/456 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGEF4 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 79/320 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 229/342 reads (67%) | called by mutect2, pindel, varscan2
- CCDC166 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 244/861 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.4720G>C p.G1574R (on ENST00000520002; = p.G1573R on NM_033225.6) | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL9 | c.6812C>T p.P2271L | Missense Mutation (SNP) | VAF 86/397 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF5B | c.284_285insC p.K96* | Frame Shift Ins (INS) | VAF 34/170 reads (20%) | called by mutect2, varscan2
- INSM2 | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 327/403 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- KNDC1 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 155/706 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NUP58 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLFM3 | c.1348G>T p.D450Y (on ENST00000338858 / NM_001288821.1; = p.D430Y on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKCG | c.459C>G p.D153E | Missense Mutation (SNP) | VAF 26/770 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- TAF1 | c.667C>T p.R223C (on ENST00000373790 / NM_138923.4; = p.R244C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/169 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TBC1D8 | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 96/424 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TDRD7 | c.1165A>C p.S389R | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGFBR3 | c.1514G>T p.C505F | Missense Mutation (SNP) | VAF 14/437 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TP53 | c.430_435del p.Q144_L145del | In Frame Del (DEL) | VAF 251/297 reads (85%) | called by mutect2, pindel, varscan2
- TTN | c.77957A>C p.Q25986P (on ENST00000591111; = p.Q18562P on NM_003319.4) | Missense Mutation (SNP) | VAF 74/327 reads (23%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VSIR | c.583G>C p.A195P | Missense Mutation (SNP) | VAF 254/288 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ARHGEF40 | c.207A>G p.Q69= | Silent (SNP) | VAF 53/178 reads (30%) | catalogued as rs375010957; called by muse, mutect2, varscan2
- CACNA1A | c.228G>A p.R76= | Silent (SNP) | VAF 162/2476 reads (7%) | called by muse, mutect2
- CPN2 | c.1377G>A p.P459= | Silent (SNP) | VAF 134/659 reads (20%) | catalogued as rs373278468; called by muse, mutect2, varscan2
- HNRNPLL | c.105G>A p.S35= | Silent (SNP) | VAF 428/659 reads (65%) | called by muse, varscan2
- HS3ST4 | c.972C>T p.I324= | Silent (SNP) | VAF 98/487 reads (20%) | catalogued as rs754703038; called by muse, mutect2, varscan2
- JCAD | c.3318G>A p.A1106= | Silent (SNP) | VAF 152/663 reads (23%) | catalogued as rs781102962, COSV64757886; called by muse, mutect2, varscan2
- LRCH4 | c.789G>T p.G263= | Silent (SNP) | VAF 118/1866 reads (6%) | called by muse, mutect2
- LRRTM4 | c.345T>A p.I115= | Silent (SNP) | VAF 71/330 reads (22%) | called by muse, mutect2, varscan2
- NUFIP2 | c.1827A>G p.Q609= | Silent (SNP) | VAF 48/371 reads (13%) | catalogued as rs1446685600, COSV56604802; called by muse, mutect2, varscan2
- POLE | c.1845C>T p.S615= | Silent (SNP) | VAF 80/314 reads (25%) | catalogued as COSV57674408; called by muse, mutect2, varscan2
- RAVER1 | c.1047C>T p.P349= | Silent (SNP) | VAF 77/399 reads (19%) | called by muse, mutect2, varscan2
- SCN4A | c.4644C>T p.S1548= | Silent (SNP) | VAF 155/511 reads (30%) | catalogued as rs751973449, COSV71127890; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TFR2 | c.330G>A p.A110= | Silent (SNP) | VAF 122/1454 reads (8%) | catalogued as rs542567285; ClinVar: likely benign; called by muse, mutect2
- UHRF1BP1 | c.4308C>A p.P1436= | Silent (SNP) | VAF 40/184 reads (22%) | called by muse, mutect2, varscan2
- WASF3 | c.1419C>T p.D473= | Silent (SNP) | VAF 125/301 reads (42%) | catalogued as rs144241776; called by muse, mutect2, varscan2
- ZNF831 | c.813C>T p.S271= | Silent (SNP) | VAF 164/797 reads (21%) | catalogued as rs369672507; called by muse, mutect2, varscan2
